Gene-level copy-number profile of tumor specimen TCGA-V1-A9O5-06A from TCGA case TCGA-V1-A9O5, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland.
Specimen TCGA-V1-A9O5-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PRAD.cc49df19-e991-46bb-a9e8-a57a480ecdbb.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-V1-A9O5-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 357 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/04169b76-f4aa-4de0-ba6e-245d085a2cde

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 122; copy number 1: 65; copy number 2: 8,251; copy number 3: 14,963; copy number 4: 27,693; copy number 5: 2,218; copy number 6: 2,649; copy number 7: 1,539; copy number 8: 322; copy number 9: 752; copy number 10: 298; copy number 11: 852; copy number 12: 337; copy number 13: 148; copy number 14: 29; copy number 16: 22; copy number 17: 4; copy number 18: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-V1-A9O5-06A-11D-A41J-01): tumor purity 0.6, ploidy 4, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 9 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:87,642,607–87,863,533, 6 genes: RPS26P38, PAPSS2, ATAD1, CFL1P1, RN7SL78P, KLLN.
- chr10:87,878,692–87,880,427, 1 gene: AC063965.2.
- chr10:110,257,064–110,257,843, 1 gene: AL360182.1.
- chr17:41,271,311–41,271,835, 1 gene: KRTAP9-11P.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 2,444 genes in 23 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:17,378,906–45,895,970, 403 genes, copy number 9 (within-gene range 8–9) (broad region; genes not listed).
- chr8:46,028,804–145,066,685, 1,534 genes, copy number 9–18 (broad region; genes not listed).
- chr10:10,776,223–11,764,070, 15 genes, copy number 10–14: AL136452.1, SFTA1P, CELF2, LINC00710, AL136369.2, AL136369.1, AL162408.1, CELF2-AS2, AL136320.1, CELF2-AS1, AC026887.1, USP6NL, AL512631.2, AL512631.1, ECHDC3.
- chr10:11,920,022–12,043,170, 1 gene, copy number 12 (within-gene range 3–12): UPF2.
- chr10:12,068,954–12,250,589, 6 genes, copy number 12 (within-gene range 7–12): DHTKD1, RNU6-88P, SEC61A2, MIR548AK, NUDT5, CDC123.
- chr10:12,349,547–12,835,545, 1 gene, copy number 14 (within-gene range 7–14): CAMK1D.
- chr10:12,563,151–13,099,652, 8 genes, copy number 14 (within-gene range 2–14): AL731559.1, MIR4480, MIR4481, MIR548Q, AL353586.1, CCDC3, RNA5SP300, RPL5P25.
- chr10:121,133,090–121,598,458, 4 genes, copy number 11 (within-gene range 2–11): RPL19P16, LINC01153, RN7SKP167, FGFR2.
- chr19:32,102,088–33,285,739, 36 genes, copy number 10: LINC01782, AC011518.1, AC074139.1, RNA5SP472, ZNF507, AC007773.1, DPY19L3, PDCD5, ANKRD27, SNORA68B, RPS12P31, RN7SL789P, AC008474.1, RGS9BP, AC008736.1, NUDT19, AC008736.2, TDRD12, AC008805.1, SLC7A9, AC008805.2, RN7SKP22, CEP89, RPL31P60, FAAP24, RHPN2, AC008521.1, AC008521.2, GPATCH1, WDR88, LRP3, AC008738.1, AC008738.7, SLC7A10, AC008738.4, AC008738.6.
- chr19:33,906,352–34,428,273, 16 genes, copy number 9: AC008556.1, RN7SL150P, AC016587.1, RPS4XP23, RPS4XP20, RPS4XP21, CHCHD2P3, LSM14A, GARRE1, RPL29P33, AC010504.1, GPI, AC092073.1, PDCD2L, RN7SL154P, AC008747.1.
- chr19:34,675,717–34,951,205, 17 genes, copy number 11: AC020910.6, ZNF302, AC020910.5, ZNF181, ZNF599, AC020910.3, LINC01801, AC008555.1, AC008555.5, AC008555.2, AC008555.4, AC008555.3, LINC00904, LINC01838, ZNF30-AS1, ZNF30, AC008555.6.
- chr19:36,259,540–37,304,395, 40 genes, copy number 9: LINC00665, AC092296.2, ZFP14, AC092296.1, AC092296.4, ZFP82, AC092296.3, ZNF566, AC092295.2, CTBP2P7, ZNF260, AC092295.1, ZNF529, ZNF529-AS1, ZNF382, ZNF461, AC074138.1, LINC01534, ZNF567, ZNF850, AC020928.1, AC020928.2, ZNF790-AS1, ZNF790, ZNF345, Y_RNA, ZNF829, RPL31P61, ZNF568, ZNF420, AC010632.3, AC010632.1, AC010632.2, AC012309.1, ZNF585A, AC012309.2, ZNF585B, ZNF383, AC016590.1, LINC01535.
- chr19:39,030,436–39,320,863, 14 genes, copy number 10: AC010605.1, ACP7, PAK4, AC011443.1, NCCRP1, SYCN, IFNL3P1, IFNL3, IFNL4, MSRB1P1, IFNL4P1, IFNL2, IFNL1, LRFN1.
- chr19:39,631,300–40,576,464, 48 genes, copy number 11 (within-gene range 3–11): AC005176.2, AC005176.1, RPS29P30, LGALS16, LGALS17A, AC005515.1, AC093063.1, RPS29P27, LGALS14, AC006133.1, CLC, LEUTX, AC005393.1, DYRK1B, MIR6719, FBL, FCGBP, PRR13P5, PSMC4, ZNF546, AC007842.1, ZNF780B, AC005614.2, ZNF780A, AC005614.1, VN1R96P, MAP3K10, TTC9B, CCNP, AKT2, AC118344.1, MIR641, RNU6-945P, C19orf47, Y_RNA, Y_RNA, PLD3, AC118344.2, MIR6796, HIPK4, PRX, SERTAD1, AC010271.2, SERTAD3, AC010271.1, BLVRB, Metazoa_SRP, SPTBN4.
- chr19:40,665,905–40,808,434, 12 genes, copy number 10 (within-gene range 3–10): NUMBL, COQ8B, RNU6-195P, ITPKC, C19orf54, SNRPA, MIA, MIA-RAB4B, RAB4B, RAB4B-EGLN2, AC008537.4, EGLN2.
- chr19:40,808,474–40,826,772, 2 genes, copy number 10 (within-gene range 5–10): CYP2T1P, CYP2F2P.
- chr19:41,708,585–42,390,297, 37 genes, copy number 9: CEACAM5, AC243967.1, CEACAM6, AC243967.2, CEACAM3, HNRNPA1P52, AC243967.3, LYPD4, DMRTC2, RPS19, MIR6797, CD79A, ARHGEF1, ERFL, RABAC1, AC010616.1, ATP1A3, GRIK5, ZNF574, POU2F2, AC010247.1, MIR4323, AC010247.2, DEDD2, AC006486.3, ZNF526, GSK3A, AC006486.1, AC006486.2, ERF, CIC, PAFAH1B3, PRR19, TMEM145, MEGF8, MIR8077, CNFN.
- chr19:43,690,002–44,536,613, 46 genes, copy number 9: AC005622.1, IRGC, SMG9, KCNN4, LYPD5, AC115522.1, ZNF283, ZNF404, AC006213.6, AC006213.2, AC006213.7, AC006213.3, ZNF45, ZNF221, ZNF155, AC006213.4, AC006213.5, AC006213.1, ZNF230, AC067968.2, ZNF222, AC067968.1, ZNF223, ZNF284, RNU6-902P, ZNF224, AC021092.1, ZNF225, ZNF234, AC138470.2, ZNF226, ZNF227, ZNF235, AC138470.1, ZNF233, AC138473.1, NDUFA3P1, ZNF112, AC245748.1, ZNF285, AC245748.2, ZNF229, ZNF285B, ZNF180, CEACAM20, AC245748.3.
- chr19:45,733,439–46,077,118, 20 genes, copy number 12: BHMG1, SIX5, AC074212.1, DM1-AS, DMPK, AC011530.1, DMWD, RSPH6A, SYMPK, AC092301.1, FOXA3, IRF2BP1, MYPOP, NANOS2, NOVA2, CCDC61, MIR769, PGLYRP1, AC007785.3, IGFL4.
- chr19:46,297,042–46,850,846, 34 genes, copy number 10: HIF3A, RNU6-924P, AC007193.2, PPP5C, AC007193.1, AC007193.3, CCDC8, PNMA8C, PNMA8A, PPP5D1, PNMA8B, AC011484.1, AC011551.1, GAPDHP38, CALM3, AC093503.1, PTGIR, GNG8, AC093503.2, DACT3, DACT3-AS1, PRKD2, RN7SL364P, MIR320E, STRN4, AC008635.1, Y_RNA, FKRP, SLC1A5, AC008622.2, AC008622.3, HNRNPMP2, AC008622.1, AP2S1.
- chr19:48,813,018–49,958,391, 108 genes, copy number 13 (within-gene range 4–13) (broad region; genes not listed).
- chr19:49,949,316–49,949,527, 1 gene, copy number 13: U3.
- chr19:50,050,589–50,823,787, 41 genes, copy number 11: AC010624.1, AC010624.4, AC010624.2, AC010624.5, IZUMO2, MYH14, Metazoa_SRP, AC008655.1, KCNC3, NR1H2, NAPSB, NAPSA, AC008655.2, POLD1, AC020909.1, SPIB, MYBPC2, FAM71E1, EMC10, AC020909.3, AC020909.2, JOSD2, ASPDH, LRRC4B, AC008743.1, SYT3, C19orf81, SHANK1, CLEC11A, GPR32P1, GPR32, AC010325.1, ACP4, AC010325.2, C19orf48, SNORD88B, SNORD88A, SNORD88C, AC010325.3, LINC01869, KLK1.

Autosomal genes at a single copy (total copy number 1): 65. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
